Somatic mutation profile of tumor specimen 0DX7FK from CCDI case PBCPJT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 15.0 years (5,471 days).
Specimen 0DX7FK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aeff76d-29fb-4f5b-8d40-8d7569c08f91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7EO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5529a293-651e-4be0-9201-579ac90ed61e

The open-access MAF lists 84 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Intron 13, 5'UTR 5, 3'UTR 3, 5'Flank 2, Nonsense Mutation 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1529A>G p.Q510R | Missense Mutation (SNP) | VAF 322/628 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs121918470, CM043070, CM052358, COSV61008620; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACO2 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 105/707 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as rs746141024; called by muse, varscan2
- ADAM29 | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 130/717 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs747440424; called by muse, varscan2
- ADD1 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 99/424 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs781597772; called by muse, varscan2
- ADSS1 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1461517172; called by muse, varscan2
- C4A | c.3537G>C p.L1179F | Missense Mutation (SNP) | VAF 140/374 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as rs781183715; called by muse, varscan2
- CDK20 | c.790C>A p.L264M (on ENST00000325303 / NM_001039803.3; = p.L243M on NM_012119.4) | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1223713527; called by muse, varscan2
- E4F1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs576266110, COSV57039949; called by muse, varscan2
- FGA | c.2539A>T p.R847* | Nonsense Mutation (SNP) | VAF 210/588 reads (36%) | catalogued as COSV57396267; called by muse, varscan2
- HGF | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 606/1614 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.48); catalogued as rs1032300573, COSV99736017; called by muse, varscan2
- LCE1B | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 444/660 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs201742584; called by muse, varscan2
- NEURL4 | c.4328C>G p.S1443C | Missense Mutation (SNP) | VAF 58/575 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100222764; called by muse, varscan2
- RPA4 | c.765G>T p.E255D | Missense Mutation (SNP) | VAF 154/421 reads (37%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.779); catalogued as COSV61265940; called by muse, varscan2
- SPATA2L | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.091); catalogued as COSV99232381; called by muse, varscan2
- TLR4 | c.1596_1598del p.F533del (on ENST00000355622 / NM_138554.5; = p.F493del on NM_003266.4) | In Frame Del (DEL) | VAF 152/725 reads (21%) | catalogued as rs1250160671; called by pindel, varscan2
- TRIM2 | c.1582C>A p.R528S (on ENST00000437508; = p.R555S on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/457 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58635738; called by muse, varscan2
- TRPM4 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as rs144767624; called by muse, varscan2
- UNC93B1 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1251067819; called by muse, varscan2
- ZNF407 | c.5114G>T p.R1705L | Missense Mutation (SNP) | VAF 138/910 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55272075; called by muse, varscan2
- ZNF668 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56213283; called by muse, varscan2
- ARHGAP36 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, varscan2
- CFAP70 | c.1281G>T p.R427S | Missense Mutation (SNP) | VAF 162/318 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, varscan2
- CFAP94 | c.328G>T p.A110S (on ENST00000320267 / NM_001352064.2; = p.A116S on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 384/964 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, varscan2
- CSNK2A3 | c.183T>A p.N61K | Missense Mutation (SNP) | VAF 132/1057 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, varscan2
- GRIN2B | c.3577G>T p.V1193L | Missense Mutation (SNP) | VAF 446/943 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.055); called by muse, varscan2
- HDX | c.1904G>T p.S635I | Missense Mutation (SNP) | VAF 150/459 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, varscan2
- HEPHL1 | c.2251A>T p.N751Y | Missense Mutation (SNP) | VAF 187/634 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, varscan2
- MISP | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.35); called by muse, varscan2
- MYH4 | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 110/862 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, varscan2
- NFAT5 | c.2338G>T p.A780S | Missense Mutation (SNP) | VAF 161/772 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, varscan2
- NPRL3 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 68/378 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, varscan2
- NWD2 | c.3115G>C p.V1039L | Missense Mutation (SNP) | VAF 125/482 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, varscan2
- OR2C3 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 125/928 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- PITPNM1 | c.3136G>T p.A1046S | Missense Mutation (SNP) | VAF 65/475 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- PKD2L1 | c.2406G>T p.L802F | Missense Mutation (SNP) | VAF 180/368 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); called by muse, varscan2
- PMS2 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 263/612 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, varscan2
- POU6F1 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, varscan2
- RECQL5 | c.2617C>A p.P873T | Missense Mutation (SNP) | VAF 64/524 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, varscan2
- RECQL5 | c.98T>G p.L33* | Nonsense Mutation (SNP) | VAF 100/784 reads (13%) | called by muse, varscan2
- SH3RF1 | c.1559C>A p.T520K | Missense Mutation (SNP) | VAF 131/608 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.343); called by muse, varscan2
- SLC1A7 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.429); called by muse, varscan2
- STOX2 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); called by muse, varscan2
- TENM2 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 123/852 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.993); called by muse, varscan2
- TNMD | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 124/352 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, varscan2
- TRIM65 | c.1544T>G p.V515G | Missense Mutation (SNP) | VAF 58/470 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, varscan2
- TTC21A | c.3906C>A p.D1302E | Missense Mutation (SNP) | VAF 85/435 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, varscan2
- VWA3B | c.3352A>G p.I1118V | Missense Mutation (SNP) | VAF 326/703 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); called by muse, varscan2
- AP000812.4 | c.786C>G p.R262= | Silent (SNP) | VAF 64/478 reads (13%) | called by muse, varscan2
- FLT3 | c.90G>T p.L30= | Silent (SNP) | VAF 72/304 reads (24%) | called by muse, varscan2
- FOXP2 | c.993G>C p.S331= | Silent (SNP) | VAF 142/1236 reads (11%) | catalogued as COSV100646128, COSV63488109; called by muse, varscan2
- GRIN2B | c.4269C>A p.A1423= | Silent (SNP) | VAF 93/889 reads (10%) | catalogued as COSV74208466; called by muse, varscan2
- LHFPL3 | c.660T>A p.S220= | Silent (SNP) | VAF 168/1200 reads (14%) | called by muse, varscan2
- MAGI3 | c.3573G>T p.V1191= | Silent (SNP) | VAF 332/981 reads (34%) | called by muse, varscan2
- OR51A4 | c.681G>T p.L227= | Silent (SNP) | VAF 400/1237 reads (32%) | called by muse, varscan2
- OR6C68 | c.705C>A p.A235= | Silent (SNP) | VAF 414/969 reads (43%) | catalogued as COSV101109997, COSV65563741; called by muse, varscan2
- PCDHGA6 | c.822C>T p.H274= | Silent (SNP) | VAF 133/846 reads (16%) | catalogued as rs756655009, COSV99542643; called by muse, varscan2
- PKDREJ | c.711G>A p.A237= | Silent (SNP) | VAF 46/438 reads (11%) | catalogued as rs532892775; called by muse, varscan2
- SCLT1 | c.348C>T p.G116= | Silent (SNP) | VAF 154/659 reads (23%) | catalogued as rs759557133; called by muse, varscan2
- SMAD5 | c.6G>A p.T2= | Silent (SNP) | VAF 124/828 reads (15%) | catalogued as rs781258434, COSV72505701; called by muse, varscan2
- TRPM4 | c.2994C>A p.G998= | Silent (SNP) | VAF 58/442 reads (13%) | called by muse, varscan2
- ADH5 | chr4:99088751 C>G | 5'Flank (SNP) | VAF 61/244 reads (25%) | called by muse, varscan2
- BAIAP2L2 | c.-15C>T | 5'UTR (SNP) | VAF 51/388 reads (13%) | catalogued as rs370101147; called by muse, varscan2
- CADM1 | c.1078+11167C>G | Intron (SNP) | VAF 116/810 reads (14%) | called by muse, varscan2
- CDK17 | c.1534+83A>G | Intron (SNP) | VAF 120/404 reads (30%) | called by muse, varscan2
- CFAP36 | c.777+21A>T | Intron (SNP) | VAF 126/790 reads (16%) | called by muse, varscan2
- CHRNB1 | c.1217+66G>A | Intron (SNP) | VAF 26/213 reads (12%) | called by muse, varscan2
- CLTC | c.2128+17G>T | Intron (SNP) | VAF 144/742 reads (19%) | called by muse, varscan2
- DNAH5 | c.2259+61del | Intron (DEL) | VAF 42/328 reads (13%) | called by pindel, varscan2
- FAM53A | c.*18C>A | 3'UTR (SNP) | VAF 30/108 reads (28%) | called by muse, varscan2
- OR6C3 | chr12:55331673 del GAA | 5'Flank (DEL) | VAF 39/254 reads (15%) | called by pindel, varscan2
- PCLAF | c.-20T>C | 5'UTR (SNP) | VAF 120/274 reads (44%) | called by muse, varscan2
- PCSK7 | c.861-62C>T | Intron (SNP) | VAF 34/104 reads (33%) | catalogued as rs963831949; called by muse, varscan2
- PKD1L2 | n.1200C>T | RNA (SNP) | VAF 83/394 reads (21%) | catalogued as rs373654606; called by muse, varscan2
- PLCD4 | c.975-36C>A | Intron (SNP) | VAF 156/293 reads (53%) | called by muse, varscan2
- PROS1 | c.260-33C>T | Intron (SNP) | VAF 39/222 reads (18%) | catalogued as rs1249860168; called by muse, varscan2
- RABAC1 | c.56+59C>T | Intron (SNP) | VAF 23/119 reads (19%) | catalogued as rs1381629552; called by muse, varscan2
- RASA1 | c.*95A>C | 3'UTR (SNP) | VAF 68/385 reads (18%) | called by muse, varscan2
- RTRAF | c.-86G>T | 5'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- SEC31A | c.2627-46T>A | Intron (SNP) | VAF 21/78 reads (27%) | catalogued as rs1314838048; called by muse, varscan2
- SELENON | c.-31G>C | 5'UTR (SNP) | VAF 22/62 reads (35%) | catalogued as rs1209094394; called by muse, varscan2
- TECRL | c.730+59T>G | Intron (SNP) | VAF 52/266 reads (20%) | catalogued as rs1370636821; called by muse, varscan2
- TRIM27 | c.*58A>G | 3'UTR (SNP) | VAF 22/98 reads (22%) | called by muse, varscan2
- TUT7 | c.-3A>T | 5'UTR (SNP) | VAF 118/550 reads (21%) | called by muse, varscan2
- ZNF324B | c.238+38C>T | Intron (SNP) | VAF 36/186 reads (19%) | called by muse, varscan2
